FM case AD13063 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/f6f0180c-f54f-486c-ae12-ee6963696afe

Female, 60.5 years: Endometrioid adenocarcinoma, NOS (ICD-O-3 8380/3) of the uterus; primary biopsied or resected from the uterus. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
